Somatic mutation profile of tumor specimen ER-ACGR-TTM1-A (aliquot ER-ACGR-TTM1-A-1-0-D-A49N-34) from EXCEPTIONAL_RESPONDERS case ER-ACGR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.1 years (19,015 days).
Specimen ER-ACGR-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f626b4e3-a340-48a1-9703-8d8c4ea4c98d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ACGR-NB1-A (Blood Derived Normal), aliquot ER-ACGR-NB1-A-1-0-D-A49N-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/605c8d27-9e30-49d0-b413-4b8a63f534e4

The open-access MAF lists 510 somatic variants for this specimen: 393 protein-altering or splice-affecting, 78 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 342, Silent 78, Nonsense Mutation 24, Frame Shift Del 14, Intron 13, 3'UTR 11, 5'UTR 8, Splice Region 8, RNA 5, Frame Shift Ins 3, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.1807C>T p.R603C (on ENST00000490131; = p.R680C on NM_000388.4) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767363250, CM952039; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 145/266 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 56/406 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC023469.1 | n.111C>T | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as rs1376178355; called by mutect2, varscan2
- ADAMTSL4 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs772032770, COSV55006430; called by muse, mutect2, varscan2
- ANO2 | c.2389G>C p.G797R (on ENST00000356134 / NM_001278597.3; = p.G801R on NM_001278596.3) | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs774552828, COSV59049454; called by muse, mutect2, varscan2
- ANO3 | c.2638G>T p.G880* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV99879604, COSV99884225; called by muse, mutect2, varscan2
- ARHGAP39 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV52767954; called by muse, mutect2, varscan2
- ARSB | c.1534G>T p.V512L | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV53730262; called by muse, mutect2, varscan2
- ATP10D | c.2051A>G p.Q684R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.102); catalogued as COSV56707599; called by muse, mutect2, varscan2
- ATP1B4 | c.763G>T p.V255L (on ENST00000218008 / NM_001142447.3; = p.V251L on NM_012069.5) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54315039; called by muse, mutect2, varscan2
- AZU1 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52142893; called by muse, mutect2, varscan2
- BMP5 | c.844A>T p.N282Y | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV63700913; called by muse, mutect2, varscan2
- CCDC171 | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1314097071; called by muse, mutect2, varscan2
- CDC123 | c.829G>T p.V277F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.183); catalogued as rs576722777; called by muse, mutect2, varscan2
- CFAP47 | c.5067G>T p.M1689I | Missense Mutation (SNP) | VAF 167/404 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV57974247, COSV57975930; called by muse, mutect2, varscan2
- CGN | c.2422G>T p.G808W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763986954; called by muse, mutect2, varscan2
- CNTNAP5 | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70505038; called by muse, mutect2, varscan2
- CRTAM | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs775161741, COSV57066614; called by muse, mutect2, varscan2
- CTAG2 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV99908851; called by muse, mutect2, varscan2
- CTSA | c.307-3C>G | Splice Region (SNP) | VAF 11/78 reads (14%) | catalogued as COSV99509919; called by muse, mutect2, varscan2
- CTTNBP2 | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs746241505, COSV50413112; called by muse, mutect2
- CYBB | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV66086047; called by muse, mutect2, varscan2
- DCC | c.545C>A p.P182Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV100502187, COSV59141828; called by muse, mutect2, varscan2
- DLG3 | c.2046G>A p.M682I (on ENST00000374360 / NM_021120.4; = p.M377I on NM_020730.3) | Missense Mutation (SNP) | VAF 144/283 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52085742, COSV99529376; called by muse, mutect2, varscan2
- DSCAM | c.6016G>C p.A2006P | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as COSV68028967; called by muse, mutect2, varscan2
- DUSP22 | c.483T>G p.D161E | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60526529; called by muse, mutect2, varscan2
- ELOA2 | c.1583C>A p.T528K | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs758290047; called by muse, mutect2, varscan2
- ERICH3 | c.3508A>G p.I1170V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1198983215; called by muse, mutect2, varscan2
- EVC2 | c.3640G>T p.A1214S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.324); catalogued as COSV60400295; called by muse, mutect2, varscan2
- FAM47C | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs374159933, COSV63726426; called by muse, varscan2
- FGF16 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101466331; called by muse, mutect2, varscan2
- FMO2 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV99269169; called by muse, mutect2, varscan2
- FRMPD2 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV59717947; called by muse, mutect2, varscan2
- FRMPD3 | c.414C>A p.F138L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as rs1245766101; called by muse, mutect2, varscan2
- FSHR | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs371488439; called by muse, mutect2, varscan2
- FSHR | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV58633511; called by muse, mutect2, varscan2
- GATA1 | c.600G>A p.E200= | Splice Region (SNP) | VAF 57/113 reads (50%) | catalogued as rs781977639; called by muse, mutect2, varscan2
- GRIA1 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV53589899; called by muse, mutect2, varscan2
- GRIK5 | c.2339G>T p.R780L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53480784; called by muse, mutect2, varscan2
- GUCY2F | c.2706del p.I903Lfs*7 | Frame Shift Del (DEL) | VAF 327/701 reads (47%) | catalogued as COSV54305791; called by mutect2, pindel, varscan2
- GYPC | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs948291339; called by muse, mutect2, varscan2
- HEPH | c.801G>T p.R267S (on ENST00000343002; = p.R321S on NM_138737.5) | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs773393350, COSV57959115; called by muse, mutect2, varscan2
- HERC6 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99910542; called by muse, mutect2, varscan2
- IPO8 | c.1714C>G p.Q572E | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763188716; called by muse, mutect2, varscan2
- ITGA7 | c.1892G>A p.R631Q (on ENST00000555728; = p.R587Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs772897434, COSV57701182; called by muse, mutect2, varscan2
- JUND | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53254874, COSV53254987; called by muse, mutect2, varscan2
- KAZN | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as rs753818530; called by muse, mutect2, varscan2
- KCNMB2 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146496237; called by muse, mutect2
- KIF2B | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV52135681; called by muse, mutect2, varscan2
- KLRD1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 66/135 reads (49%) | catalogued as COSV60273928; called by muse, mutect2, varscan2
- KRT78 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58853401; called by muse, mutect2, varscan2
- KRTAP19-3 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.551); catalogued as rs1434494164, COSV61854570; called by muse, mutect2, varscan2
- LRP1B | c.7562G>T p.G2521V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776244285; called by muse, mutect2, varscan2
- LRRC37A3 | c.4087A>G p.R1363G | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1285423615, COSV58534496; called by muse, mutect2
- LRRC66 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV58634492; called by muse, mutect2, varscan2
- LSP1 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV61134802; called by muse, varscan2
- LTBP2 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV56206699; called by muse, mutect2, varscan2
- MAGEA3 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 56/125 reads (45%) | catalogued as COSV100938982; called by muse, mutect2, varscan2
- MAGEC1 | c.1396A>T p.T466S | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.011); catalogued as COSV99594771; called by muse, mutect2, varscan2
- MGAM | c.5179C>A p.H1727N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV101527631; called by muse, mutect2, varscan2
- MLLT10 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV57004234; called by muse, mutect2, varscan2
- MOSPD1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 137/389 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66189560; called by muse, mutect2, varscan2
- MYH2 | c.4536G>C p.Q1512H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55434000; called by muse, mutect2, varscan2
- NBPF14 | c.2615A>G p.E872G | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1430421905; called by muse, varscan2
- NCKAP5 | c.4361C>A p.A1454D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1345739425, COSV58441311, COSV58448724; called by muse, mutect2, varscan2
- NEGR1 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs754424709, COSV100161940; called by muse, mutect2, varscan2
- NLRP7 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100053441; called by muse, mutect2, varscan2
- NTN1 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV51480225; called by muse, mutect2, varscan2
- NUP210L | c.4648C>T p.R1550* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as rs1313658047, COSV55141047; called by muse, mutect2, varscan2
- OR7D4 | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs147697203; called by muse, mutect2, varscan2
- OSTN | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100174339; called by muse, mutect2, varscan2
- PCDHB3 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.006); catalogued as rs782087248, COSV99166583; called by muse, mutect2, varscan2
- PGLYRP3 | c.325del p.Q109Rfs*17 | Frame Shift Del (DEL) | VAF 46/156 reads (29%) | catalogued as COSV51950452, COSV51953178, COSV99319411; called by mutect2, pindel, varscan2
- PIGC | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.816); catalogued as COSV51130047; called by muse, mutect2, varscan2
- PLCB3 | c.3379C>T p.R1127W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1361432461, COSV54192151; called by muse, mutect2, varscan2
- PLCB4 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as COSV53794730; called by muse, mutect2, varscan2
- PNLIP | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.782); catalogued as rs751672961; called by muse, mutect2, varscan2
- PPP1R12A | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418875618; called by muse, mutect2, varscan2
- PPWD1 | c.969C>T p.S323= | Splice Region (SNP) | VAF 26/90 reads (29%) | catalogued as rs772604962; called by muse, mutect2, varscan2
- PREX1 | c.4687G>A p.G1563S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs147602754; called by muse, mutect2, varscan2
- PRPF19 | c.1441G>T p.V481L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV57129599; called by muse, mutect2
- PSG1 | c.1037C>A p.S346* | Nonsense Mutation (SNP) | VAF 33/63 reads (52%) | catalogued as COSV99741358, COSV99741709; called by muse, mutect2, varscan2
- PTCHD3 | c.2035T>A p.C679S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs370492754; called by muse, mutect2, varscan2
- PTPRD | c.4396G>A p.D1466N | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV61973374; called by muse, mutect2, varscan2
- PUF60 | c.436C>T p.R146C (on ENST00000526683 / NM_001362896.2; = p.R129C on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57592319; called by muse, mutect2, varscan2
- RGS9 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1183348011, COSV52229562; called by muse, mutect2, varscan2
- RMI2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56964380; called by muse, mutect2, varscan2
- RNF207 | c.170G>C p.R57P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV65008609; called by muse, mutect2, varscan2
- ROS1 | c.4375G>T p.A1459S | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV63852809; called by muse, mutect2, varscan2
- RYR1 | c.14640G>A p.M4880I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100615675; called by muse, mutect2, varscan2
- SALL3 | c.2601C>A p.N867K | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs766510581; called by muse, mutect2, varscan2
- SCN10A | c.5303C>A p.A1768E | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71862548; called by muse, mutect2, varscan2
- SETD1B | c.5248G>A p.E1750K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57352117, COSV57353239; called by muse, mutect2, varscan2
- SGF29 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1445381813; called by muse, mutect2, varscan2
- SHROOM2 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66609466; called by muse, mutect2, varscan2
- SLC28A2 | c.1153del p.E385Rfs*11 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as rs996687181, COSV61664223; called by mutect2, pindel, varscan2
- SLN | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs375547331; called by muse, mutect2, varscan2
- SMARCC1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV54379568; called by muse, mutect2
- SNCB | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 90/150 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV59435676; called by muse, mutect2, varscan2
- SOX6 | c.1841G>T p.R614L (on ENST00000528429 / NM_001145819.2; = p.R587L on NM_017508.3) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1242397325, COSV100321255, COSV57053359; called by muse, mutect2, varscan2
- SPATA31E1 | c.4161C>A p.H1387Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs138857078; called by muse, mutect2, varscan2
- SRC | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV62440259; called by muse, mutect2, varscan2
- ST14 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as rs756292228, COSV99598345; called by muse, mutect2, varscan2
- STS | c.1060G>T p.G354* | Nonsense Mutation (SNP) | VAF 64/276 reads (23%) | catalogued as CM159957, COSV54268729; called by muse, mutect2, varscan2
- SUCLG2 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as rs201284259, COSV56203065, COSV56213506; called by muse, mutect2, varscan2
- SULT6B1 | c.725T>C p.M242T (on ENST00000535679 / NM_001367551.1; = p.M204T on NM_001032377.2) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1234816819; called by muse, mutect2, varscan2
- TCF23 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.763); catalogued as COSV99940271, COSV99940412; called by muse, mutect2, varscan2
- TEX26 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 70/106 reads (66%) | catalogued as COSV66839730; called by muse, varscan2
- THSD4 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778609918; called by muse, mutect2, varscan2
- TIAM1 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs754307192, COSV54556810; called by muse, mutect2, varscan2
- TIRAP | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs780635079, COSV101201641; called by muse, mutect2, varscan2
- TLN1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59205530; called by muse, varscan2
- TMEM209 | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1448986306; called by muse, mutect2, varscan2
- TMPRSS9 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs774871976; called by muse, mutect2, varscan2
- TRIOBP | c.6913G>A p.D2305N (on ENST00000644935 / NM_001039141.3; = p.D592N on NM_007032.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as rs1420178992; called by muse, mutect2, varscan2
- TRPM6 | c.4075G>C p.E1359Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.08); catalogued as COSV62515059; called by muse, mutect2, varscan2
- UNC80 | c.6349C>G p.Q2117E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs1372935806; called by muse, mutect2, varscan2
- VWDE | c.3064G>A p.D1022N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359256759; called by muse, mutect2, varscan2
- WIPF1 | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV55812161; called by muse, mutect2, varscan2
- WNT16 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1245905216; called by muse, mutect2, varscan2
- WT1 | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.257); catalogued as COSV100189181, COSV60072025; called by muse, mutect2, varscan2
- XIRP1 | c.3979C>T p.P1327S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745921106; called by muse, mutect2, varscan2
- ZFHX4 | c.10677C>A p.C3559* | Nonsense Mutation (SNP) | VAF 41/84 reads (49%) | catalogued as COSV51498119; called by muse, mutect2, varscan2
- ZGRF1 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as COSV104387435; called by muse, mutect2, varscan2
- ZNF215 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528351583, COSV53493878, COSV53494084; called by muse, mutect2, varscan2
- ZNF415 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV54703931; called by muse, mutect2, varscan2
- ZNF423 | c.2238C>A p.H746Q (on ENST00000563137 / NM_001379286.1; = p.H738Q on NM_015069.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99280183; called by muse, mutect2, varscan2
- ZNF474 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1298047216; called by muse, mutect2, varscan2
- ZNF506 | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV71354692; called by muse, mutect2, varscan2
- ZNF544 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1201369364, COSV54136466; called by muse, mutect2, varscan2
- ZNF618 | c.704C>T p.T235M (on ENST00000374126 / NM_001318042.2; = p.T203M on NM_133374.2) | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.563); catalogued as rs372130052; called by muse, mutect2, varscan2
- ABCA13 | c.11042G>C p.C3681S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ABCC2 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ACVR1C | c.1427T>A p.L476H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS3 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADAMTSL1 | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ADCY10 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRA1 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADGRG4 | c.5079G>T p.K1693N | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- AFG3L2 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- AFM | c.1237C>A p.Q413K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ALAS2 | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ALDH18A1 | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMOT | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 108/184 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ANTXR1 | c.1301A>G p.N434S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ARHGAP5 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF1 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 67/108 reads (62%) | called by muse, mutect2, varscan2
- ARID3C | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ARX | c.1658del p.P553Rfs*104 | Frame Shift Del (DEL) | VAF 104/257 reads (40%) | called by mutect2, pindel, varscan2
- ASIC2 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATP7A | c.1471T>A p.Y491N | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ATXN2 | c.2209A>T p.N737Y (on ENST00000550104; = p.N577Y on NM_002973.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- AUNIP | c.101C>G p.T34S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- BAZ2B | c.4988G>T p.G1663V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- BCKDK | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BRMS1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf71 | c.3100C>T p.H1034Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- C2orf78 | c.2312C>G p.A771G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- C5orf47 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 154/217 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C7 | c.685T>A p.S229T | Missense Mutation (SNP) | VAF 58/398 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CACNA1E | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CACNA2D1 | c.1781C>A p.S594Y (on ENST00000356253 / NM_001366867.1; = p.S575Y on NM_000722.4) | Missense Mutation (SNP) | VAF 120/346 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- CAMK1G | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAMSAP1 | c.3318G>T p.E1106D | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC22 | c.462C>G p.H154Q | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC39 | c.2447C>G p.T816R | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CCDC74A | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CDC7 | c.1583A>T p.Y528F | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDX1 | c.796T>C p.*266Qext*55 | Nonstop Mutation (SNP) | VAF 40/65 reads (62%) | called by muse, mutect2, varscan2
- CHAT | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNDP1 | c.641A>T p.K214M | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CNGA4 | c.1151del p.E384Gfs*54 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- COL19A1 | c.2749G>T p.G917* | Nonsense Mutation (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- COL6A1 | c.825del p.L276Sfs*25 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- COLEC11 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CPEB1 | c.1733G>C p.C578S (on ENST00000617958; = p.C513S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CRYBA2 | c.149T>A p.V50E | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP24A1 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYSLTR2 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DDN | c.1914C>G p.S638R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DLG3 | c.2047G>A p.E683K (on ENST00000374360 / NM_021120.4; = p.E378K on NM_020730.3) | Missense Mutation (SNP) | VAF 141/278 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.3673del p.Q1225Rfs*68 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.349dup p.L117Pfs*38 (on ENST00000321322; = p.L57Pfs*38 on NM_020693.4) | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- DST | c.16367G>A p.G5456E (on ENST00000361203 / NM_001374722.1; = p.G3044E on NM_015548.5) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EAF1 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ELMO1 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ENPEP | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVX1 | c.1151del p.F384Sfs*82 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- FAM47A | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- FAM47A | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 116/230 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- FANCI | c.3403A>C p.I1135L (on ENST00000310775 / NM_001376911.1; = p.I1075L on NM_018193.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FANCM | c.2898G>C p.E966D | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FHL1 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLT4 | c.2848G>T p.A950S | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FLYWCH1 | c.1042G>T p.V348L (on ENST00000253928 / NM_001308068.2; = p.V347L on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXD3 | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- FPR1 | c.922T>A p.F308I | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FRRS1 | c.1569G>T p.W523C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- FUBP1 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 147/297 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GABRR2 | c.1046_1047insA p.T350Hfs*34 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- GALNT13 | c.1334T>A p.M445K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- GALNT13 | c.1442G>T p.C481F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GHRHR | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GLI1 | c.2671G>T p.G891W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GP9 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GPI | c.1168G>C p.A390P | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GPR149 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN3A | c.1611C>A p.C537* | Nonsense Mutation (SNP) | VAF 65/103 reads (63%) | called by muse, mutect2, varscan2
- GRIN3A | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- HAUS7 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- HCN1 | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- HDAC2 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HDAC4 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- HEMGN | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- HEPH | c.800G>T p.R267M (on ENST00000343002; = p.R321M on NM_138737.5) | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HGFAC | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HGS | c.2243C>G p.P748R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HIVEP2 | c.2498C>A p.P833H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HMCN1 | c.12827A>C p.Q4276P | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- HNRNPH2 | c.632A>T p.D211V | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HNRNPL | c.912G>C p.Q304H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- HPSE | c.1330A>T p.R444W | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- HSD17B7 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGSF1 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- IL1RAPL2 | c.891A>T p.E297D | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INTS6L | c.395A>T p.N132I | Missense Mutation (SNP) | VAF 153/795 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- IPCEF1 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- IQUB | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ITGA4 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 33/145 reads (23%) | called by muse, mutect2, varscan2
- ITPR3 | c.372C>A p.L124= | Splice Region (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- KCND1 | c.1663A>T p.S555C | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KCND2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNMB2 | c.608C>A p.P203Q | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0232 | c.2843T>C p.V948A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1755 | c.1477C>A p.H493N | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KLF4 | c.886A>T p.N296Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- KLHDC1 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KLHL13 | c.922T>C p.C308R | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KRIT1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, varscan2
- KRT34 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KRTAP4-12 | c.410A>T p.Q137L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, varscan2
- LARP1 | c.2740A>G p.T914A (on ENST00000518297 / NM_033551.3; = p.T837A on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LCLAT1 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- LEPROTL1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LMNB2 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LRP2 | c.10910C>A p.P3637Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRC19 | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- LRRC7 | c.2907G>T p.R969S (on ENST00000651989 / NM_001370785.2; = p.R936S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LSP1 | c.134A>C p.Q45P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.185); called by muse, varscan2
- MAGIX | c.611T>G p.V204G | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAK16 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAPK14 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.075); called by muse, mutect2
- MAPK7 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAX | c.198del p.A67Pfs*103 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- MBNL1 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MCM10 | c.1491G>C p.L497F (on ENST00000484800 / NM_182751.3; = p.L496F on NM_018518.5) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- MFSD9 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKKS | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MKRN3 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- MPPED2 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- MPPED2 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MROH2A | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPS10 | c.389A>T p.H130L | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR1 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MXRA5 | c.7696G>T p.A2566S | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- MYH13 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- MYH2 | c.204G>T p.A68= | Splice Region (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- MYLK | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NADSYN1 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NAGK | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- NEK1 | c.2686G>T p.D896Y | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NIT2 | c.277T>G p.L93V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, varscan2
- NLRP4 | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR1H3 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRK | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.4973A>G p.Y1658C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NUMB | c.1461C>G p.F487L (on ENST00000355058; = p.F476L on NM_003744.5) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- NUP50 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- NUTM2G | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUTM2G | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NXF3 | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 146/281 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPN1LW | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR2M2 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- OR4N2 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- OR56A3 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD5 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PDCL2 | c.117A>T p.K39N | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PDE2A | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- PDE7B | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZD2 | c.3100C>G p.L1034V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- PDZRN3 | c.1191C>A p.Y397* | Nonsense Mutation (SNP) | VAF 47/67 reads (70%) | called by muse, mutect2, varscan2
- PER2 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHC3 | c.2533G>C p.D845H (on ENST00000494943 / NM_001308116.2; = p.D857H on NM_024947.4) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHF21B | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIK3CA | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PKHD1 | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PLCB1 | c.3252A>C p.K1084N | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PLEC | c.12631G>T p.E4211* (on ENST00000322810 / NM_201380.4; = p.E4101* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- PLEC | c.5212G>T p.V1738L (on ENST00000322810 / NM_201380.4; = p.V1628L on NM_000445.5) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLXNB3 | c.5341G>T p.A1781S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- POLR3A | c.2986G>T p.E996* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- POTEG | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 142/1844 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- PPAN-P2RY11 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- PPP1R3D | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PPP1R3F | c.809del p.G270Afs*56 | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | called by mutect2, pindel, varscan2
- PRDM10 | c.106A>T p.I36F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRF1 | c.422G>T p.S141I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKX | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRLR | c.1516C>G p.P506A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PSMB5 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, varscan2
- PXN | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALGAPA2 | c.877A>T p.K293* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- RBM20 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RBM26 | c.1082G>T p.R361M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RGPD2 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RGS12 | c.2558C>T p.S853F | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS4 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- RUNDC3A | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- RWDD4 | c.108A>T p.I36= | Splice Region (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- SCN2A | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 138/408 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA3D | c.2256C>A p.H752Q | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SEMA4D | c.1451A>G p.N484S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6D | c.2640T>A p.N880K (on ENST00000316364 / NM_153618.2; = p.N818K on NM_020858.2) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SFMBT2 | c.1217G>C p.R406P | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC25A13 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC39A12 | c.793T>A p.C265S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- SLC39A2 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC7A13 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SMARCA1 | c.2428A>G p.T810A | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMG8 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SMIM2 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- SNAP91 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SOX17 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- SOX5 | c.1716A>T p.R572S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP2 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- SP8 | c.1396G>C p.A466P (on ENST00000361443 / NM_198956.4; = p.A484P on NM_182700.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A1 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- SPEF2 | c.567A>T p.R189S | Missense Mutation (SNP) | VAF 172/429 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- SSH1 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ST8SIA6 | c.732T>A p.Y244* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.398G>C p.C133S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STS | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5 | c.1523C>G p.S508C | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TACR1 | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TADA2A | c.490del p.D164Tfs*24 | Frame Shift Del (DEL) | VAF 57/123 reads (46%) | called by mutect2, pindel, varscan2
- TBK1 | c.997A>T p.T333S | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TFEC | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- THRA | c.1140C>A p.Y380* | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- TLN1 | c.1549G>C p.D517H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM126B | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMEM94 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TNRC6B | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 149/237 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TOPAZ1 | c.3628G>A p.A1210T | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- TP53 | c.723dup p.C242Lfs*22 | Frame Shift Ins (INS) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- TPGS1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- TPTE | c.666G>C p.R222= (on ENST00000618007 / NM_199261.4; = p.R204= on NM_199259.4) | Splice Region (SNP) | VAF 71/310 reads (23%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.3113G>T p.G1038V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRHDE | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM38 | c.1246C>G p.L416V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TRPM3 | c.1776del p.F593Sfs*18 (on ENST00000357533 / NM_001366142.2; = p.F426Sfs*17 on NM_020952.6) | Frame Shift Del (DEL) | VAF 32/63 reads (51%) | called by mutect2, pindel, varscan2
- TSHZ1 | c.643G>C p.G215R (on ENST00000580243 / NM_001308210.2; = p.G170R on NM_005786.6) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TTI2 | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, varscan2
- TTN | c.82778C>A p.P27593Q (on ENST00000591111; = p.P20169Q on NM_003319.4) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TTN | c.56458C>A p.L18820I (on ENST00000591111; = p.L11396I on NM_003319.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TTN | c.10701G>T p.L3567F (on ENST00000591111; = p.L3521F on NM_003319.4) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- TUT7 | c.3529G>T p.V1177L | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- UACA | c.3743C>A p.A1248D | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- UGT2A1 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- USH2A | c.5754G>T p.E1918D | Missense Mutation (SNP) | VAF 77/137 reads (56%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VAV1 | c.2130-2A>T p.X710_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- VIRMA | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VLDLR | c.1579A>G p.I527V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- WDFY3 | c.1644G>T p.L548F | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- WDR5B | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- WDR87 | c.3851G>T p.W1284L | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XPOT | c.2430G>C p.M810I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- YLPM1 | c.801_802del p.S267Rfs*8 | Frame Shift Del (DEL) | VAF 42/87 reads (48%) | called by mutect2, pindel, varscan2
- ZBBX | c.257_260delinsTTT p.K86Ifs*2 | Frame Shift Del (DEL) | VAF 132/328 reads (40%) | called by pindel, varscan2*
- ZDBF2 | c.2598A>T p.E866D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC14 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZFHX4 | c.4727C>G p.A1576G | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ZFHX4 | c.5282C>T p.T1761I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZMYM4 | c.2139G>T p.K713N | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ZNF200 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ZNF423 | c.2134G>T p.V712L (on ENST00000563137 / NM_001379286.1; = p.V704L on NM_015069.4) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ZNF536 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ZNF630 | c.1438C>T p.L480F | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZNF695 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 81/133 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNF75D | c.1309C>A p.H437N | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZRSR2 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 133/282 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ABCC11 | c.1305T>G p.P435= | Silent (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- ANAPC1 | c.1164T>C p.N388= | Silent (SNP) | VAF 44/406 reads (11%) | called by muse, mutect2
- ARHGAP32 | c.5604T>G p.P1868= (on ENST00000310343 / NM_001378025.1; = p.P1519= on NM_014715.4) | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.2538G>T p.R846= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV99392217; called by muse, mutect2, varscan2
- ASB2 | c.1074C>G p.L358= | Silent (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- ATRNL1 | c.1071A>T p.G357= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- BACH2 | c.1227G>T p.S409= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV57592225; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4011G>T p.G1337= | Silent (SNP) | VAF 114/177 reads (64%) | catalogued as rs765622507; called by muse, mutect2, varscan2
- BTAF1 | c.3258G>A p.L1086= | Silent (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- C1QL2 | c.546C>T p.T182= | Silent (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- C20orf194 | c.2472G>T p.L824= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- CACNA1F | c.4425C>A p.G1475= | Silent (SNP) | VAF 57/115 reads (50%) | catalogued as rs1557106028; called by muse, mutect2, varscan2
- CAMK1G | c.138G>T p.G46= | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- CD1B | c.291A>G p.R97= | Silent (SNP) | VAF 50/283 reads (18%) | called by muse, mutect2, varscan2
- CD1E | c.1047C>A p.L349= | Silent (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- CDH12 | c.2253C>G p.L751= | Silent (SNP) | VAF 43/163 reads (26%) | called by muse, mutect2, varscan2
- CDKN2B | c.411G>T p.G137= | Silent (SNP) | VAF 46/203 reads (23%) | called by muse, mutect2, varscan2
- CEP162 | c.1125C>T p.A375= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs762251210; called by muse, mutect2, varscan2
- CNTN1 | c.1332A>G p.P444= | Silent (SNP) | VAF 37/147 reads (25%) | called by muse, mutect2, varscan2
- DACH2 | c.1755T>A p.G585= | Silent (SNP) | VAF 59/190 reads (31%) | called by muse, mutect2, varscan2
- DAZAP1 | c.945T>C p.T315= | Silent (SNP) | VAF 50/86 reads (58%) | called by muse, mutect2, varscan2
- DNAH5 | c.6393C>T p.A2131= | Silent (SNP) | VAF 75/191 reads (39%) | called by muse, mutect2, varscan2
- DNAJC14 | c.891G>T p.R297= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- DOCK3 | c.5569C>A p.R1857= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV56552481; called by muse, mutect2, varscan2
- DSPP | c.2610C>T p.S870= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs542734402; called by muse, mutect2, varscan2
- FLNA | c.2064C>G p.A688= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs782738252, COSV61045865; called by muse, mutect2, varscan2
- GLIPR1L1 | c.339C>A p.A113= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- GPR179 | c.276C>T p.P92= | Silent (SNP) | VAF 17/26 reads (65%) | called by muse, mutect2, varscan2
- GRIA1 | c.1720C>A p.R574= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs763355837, COSV53615269; called by muse, mutect2, varscan2
- GRM1 | c.2520C>T p.A840= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- HUWE1 | c.2043C>T p.I681= | Silent (SNP) | VAF 56/98 reads (57%) | called by muse, mutect2, varscan2
- JPH4 | c.960C>A p.T320= | Silent (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- KCND3 | c.285C>G p.L95= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100137064; called by muse, mutect2, varscan2
- KIAA1549L | c.4317C>A p.A1439= (on ENST00000321505; = p.A1736= on NM_012194.3) | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV100380932; called by muse, mutect2, varscan2
- KIF5A | c.468G>T p.V156= | Silent (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- LRRC37A | c.3690C>A p.A1230= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- LRRC66 | c.2565A>T p.T855= | Silent (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- MCHR1 | c.663G>C p.T221= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV50760705; called by muse, mutect2, varscan2
- MYO1C | c.1344C>G p.L448= (on ENST00000648651 / NM_001080779.2; = p.L413= on NM_033375.5) | Silent (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- NUTM2A | c.489G>T p.P163= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV101095729; called by muse, mutect2, varscan2
- OR1J2 | c.231T>A p.T77= | Silent (SNP) | VAF 83/133 reads (62%) | called by muse, mutect2, varscan2
- OR2G6 | c.726G>C p.S242= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as rs552819557, COSV58573606, COSV58575678; called by muse, mutect2, varscan2
- P2RX1 | c.771C>T p.I257= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs772210541; called by mutect2, varscan2
- PCSK6 | c.1068G>T p.S356= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs188547015, COSV100084047, COSV59339889; called by mutect2, varscan2
- PDZD4 | c.1458C>G p.P486= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV51249266; called by muse, mutect2, varscan2
- PGLYRP2 | c.1554G>T p.A518= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- PHRF1 | c.2604G>A p.P868= (on ENST00000264555 / NM_001286581.2; = p.P867= on NM_020901.4) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs541916891, COSV99213389; called by muse, mutect2, varscan2
- PNMA3 | c.72G>A p.L24= | Silent (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- PPP4R2 | c.651C>A p.T217= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as rs1327877853, COSV55597439; called by muse, mutect2
- PRPF19 | c.1440G>T p.G480= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- PRSS8 | c.9G>A p.Q3= | Silent (SNP) | VAF 51/81 reads (63%) | catalogued as rs562510374; called by muse, mutect2, varscan2
- PTCHD3 | c.462C>G p.T154= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV71257196; called by muse, mutect2, varscan2
- RNF125 | c.27C>T p.S9= | Silent (SNP) | VAF 41/62 reads (66%) | called by muse, mutect2, varscan2
- RNF138 | c.75C>G p.L25= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs369363220; called by muse, mutect2, varscan2
- RTL1 | c.1764T>A p.S588= | Silent (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- SCML1 | c.432A>T p.S144= (on ENST00000380041 / NM_001037540.3; = p.S117= on NM_006746.6) | Silent (SNP) | VAF 86/292 reads (29%) | called by muse, mutect2, varscan2
- SCML1 | c.831T>C p.P277= (on ENST00000380041 / NM_001037540.3; = p.P250= on NM_006746.6) | Silent (SNP) | VAF 112/215 reads (52%) | catalogued as COSV66240315; called by muse, mutect2, varscan2
- SEMA4G | c.600A>G p.P200= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- SHBG | c.240A>G p.P80= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs762304200; called by muse, mutect2, varscan2
- SIGMAR1 | c.246G>A p.V82= | Silent (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1335T>C p.Y445= | Silent (SNP) | VAF 37/139 reads (27%) | catalogued as rs750899779; called by muse, mutect2, varscan2
- SLC38A4 | c.18G>C p.L6= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- SLC9A6 | c.1683C>G p.L561= | Silent (SNP) | VAF 100/331 reads (30%) | called by muse, mutect2, varscan2
- SNAI2 | c.522G>A p.L174= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs753970426, COSV50078705; called by muse, mutect2, varscan2
- SPIN2A | c.447G>T p.G149= | Silent (SNP) | VAF 276/592 reads (47%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.1047C>A p.A349= | Silent (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- STEAP2 | c.1296T>C p.F432= | Silent (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
- STIM2 | c.186A>T p.T62= | Silent (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- TAS1R2 | c.1362A>G p.Q454= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- TEK | c.3072T>C p.Y1024= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV101193232; called by muse, mutect2, varscan2
- TEX14 | c.3807T>C p.D1269= (on ENST00000240361 / NM_001201457.2; = p.D1223= on NM_031272.5) | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- TRANK1 | c.3936T>C p.G1312= | Silent (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- TRPM6 | c.4074A>C p.A1358= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- VANGL1 | c.808C>T p.L270= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- ZNF10 | c.180A>G p.P60= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs886075930; called by muse, mutect2, varscan2
- ZNF184 | c.1419T>G p.P473= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV53005075; called by muse, mutect2, varscan2
- ZNF317 | c.1089G>A p.A363= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs150750454, COSV56110915; called by muse, mutect2, varscan2
- ZNF593 | c.63G>A p.A21= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs1339350870, COSV54631214; called by muse, varscan2
- BTAF1 | c.-24G>A | 5'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- CCDC140 | n.830G>T | RNA (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- CCNQ | c.*73C>T | 3'UTR (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
- CEP20 | chr16:15888611 C>T | 5'Flank (SNP) | VAF 7/30 reads (23%) | catalogued as rs201357085; called by muse, mutect2, varscan2
- CHMP1B | c.*2156A>T | 3'UTR (SNP) | VAF 49/77 reads (64%) | called by muse, mutect2, varscan2
- CREM | c.508+19G>C | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as COSV59769727; called by muse, mutect2, varscan2
- CYB5R1 | c.-12del | 5'UTR (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- DCAF4L2 | c.-8C>A | 5'UTR (SNP) | VAF 19/76 reads (25%) | catalogued as COSV60483271; called by muse, mutect2, varscan2
- FGF13 | c.50-127367G>C | Intron (SNP) | VAF 21/130 reads (16%) | called by muse, varscan2
- FGF13 | c.50-127380G>A | Intron (SNP) | VAF 50/135 reads (37%) | called by muse, varscan2
- GNL3 | c.-11C>T | 5'UTR (SNP) | VAF 8/26 reads (31%) | catalogued as rs779835399; called by muse, mutect2, varscan2
- GPR35 | c.*305G>T | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- GRIK1 | c.1207-1083T>C | Intron (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2847+1421G>A | Intron (SNP) | VAF 17/28 reads (61%) | catalogued as rs1559222079, rs56387830, COSV56221201, COSV56221622; called by muse, mutect2, varscan2
- ITPRIPL2 | c.*2238del | 3'UTR (DEL) | VAF 4/35 reads (11%) | called by pindel, varscan2
- KRTAP4-1 | c.-368A>C | 5'UTR (SNP) | VAF 27/116 reads (23%) | called by muse, mutect2, varscan2
- MAD2L2 | c.332+9C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- MCF2 | c.-4C>T | 5'UTR (SNP) | VAF 66/169 reads (39%) | called by muse, mutect2, varscan2
- MED14 | c.*2180G>T | 3'UTR (SNP) | VAF 189/631 reads (30%) | catalogued as COSV59948082; called by muse, mutect2, varscan2
- MMP26 | c.-145+92784C>A | Intron (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-4667G>C | Intron (SNP) | VAF 14/92 reads (15%) | catalogued as rs977143683; called by muse, varscan2
- MPRIP | c.2164-4543G>A | Intron (SNP) | VAF 15/60 reads (25%) | called by muse, varscan2
- NHSL2 | c.-346C>A | 5'UTR (SNP) | VAF 55/93 reads (59%) | called by muse, mutect2, varscan2
- OFCC1 | n.537del | RNA (DEL) | VAF 34/82 reads (41%) | called by mutect2, pindel, varscan2
- OR3A4P | n.1118C>A | RNA (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- PAQR8 | chr6:52407713 G>T | 3'Flank (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- SERTM1 | c.*1236T>G | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as rs1273025608; called by muse, mutect2, varscan2
- SH2D1A | c.-4G>C | 5'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- SLC17A3 | c.304-218G>A | Intron (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- SORBS1 | c.2129-1227G>T | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- SPRY3 | c.*451C>A | 3'UTR (SNP) | VAF 67/175 reads (38%) | catalogued as rs1301088531; called by muse, mutect2, varscan2
- SPRY3 | c.*7547C>A | 3'UTR (SNP) | VAF 102/267 reads (38%) | called by muse, mutect2, varscan2
- SSPOP | n.11550del | RNA (DEL) | VAF 26/66 reads (39%) | called by pindel, varscan2
- SYNRG | c.78-174G>A | Intron (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- TLX1NB | n.993C>A | RNA (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- TRMT10C | c.*251A>G | 3'UTR (SNP) | VAF 21/116 reads (18%) | catalogued as rs1286708801; called by muse, mutect2, varscan2
- UBE2D1 | c.399-25C>G | Intron (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ZNF275 | c.*778C>A | 3'UTR (SNP) | VAF 108/345 reads (31%) | called by muse, mutect2, varscan2
- ZNF691 | c.*114G>C | 3'UTR (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
